Somatic mutation profile of tumor specimen MMRF_1900_1_BM_CD138pos (aliquot MMRF_1900_1_BM_CD138pos_T1_KBS5U_L05560) from MMRF case MMRF_1900, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.6 years (28,350 days).
Specimen MMRF_1900_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5087604-26e7-47ba-831a-a1d56316fdaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1900_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1900_1_PB_Whole_C3_KBS5U_L05582; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a7b73ab-2c56-48f8-b851-9d967781c895

The open-access MAF lists 199 somatic variants for this specimen: 74 protein-altering or splice-affecting, 28 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, 3'UTR 58, Silent 28, Intron 21, 5'UTR 10, Frame Shift Del 5, 5'Flank 5, Nonsense Mutation 2, RNA 2, 3'Flank 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 25/150 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs758736365, COSV100717717; called by muse, mutect2, varscan2
- ACTG1 | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV59511520; called by muse, mutect2, varscan2
- ALX4 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368050443; called by muse, mutect2, varscan2
- CRYBB3 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.505); catalogued as rs201949776, COSV99309165; called by muse, mutect2, varscan2
- DNMT1 | c.3707A>G p.N1236S | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768280180; called by muse, mutect2, varscan2
- DOP1B | c.4591G>A p.G1531R | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767936629, COSV101215223; called by muse, mutect2, varscan2
- EMC10 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs369893864; called by muse, mutect2, varscan2
- FCGBP | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 121/385 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.394); catalogued as rs147183093; called by muse, mutect2, varscan2
- GABRG2 | c.1268G>A p.R423H (on ENST00000361925 / NM_001375343.1; = p.R383H on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/214 reads (68%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs528036202, COSV62716272, COSV62721034; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- HIP1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as rs782598992; called by muse, mutect2, varscan2
- IFRD2 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs781808384, COSV100269395; called by muse, mutect2, varscan2
- IGHV2-70 | c.259A>T p.R87W | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs568002484; called by muse, varscan2
- IGHV2-70 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs373039668; called by muse, varscan2
- LENG8 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1250795272; called by muse, mutect2
- MAMLD1 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 280/284 reads (99%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.54); catalogued as rs782768143; called by muse, mutect2, varscan2
- MCF2L | c.235C>T p.R79C (on ENST00000375608; = p.R47C on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs144497036; called by muse, mutect2, varscan2
- NKAP | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57630392; called by muse, mutect2
- NOS1 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 126/246 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs766368147, COSV100500330, COSV57606827; called by muse, mutect2, varscan2
- PCLO | c.13607A>G p.K4536R | Missense Mutation (SNP) | VAF 103/294 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV61639634; called by muse, mutect2, varscan2
- PCSK1 | c.1095+1G>A p.X365_splice | Splice Site (SNP) | VAF 13/84 reads (15%) | catalogued as rs1301652826, CS136272, CS136273; called by muse, mutect2, varscan2
- PLEKHA5 | c.1994C>T p.T665M | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as rs528534713; called by muse, mutect2, varscan2
- RXRA | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.739); catalogued as COSV62684005; called by muse, mutect2, varscan2
- SARDH | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as COSV100898421; called by muse, mutect2, varscan2
- SERPINC1 | c.1381C>G p.P461A | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV62929098; called by muse, mutect2
- TDRP | c.188G>T p.R63I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.172); catalogued as COSV100138669; called by muse, mutect2
- TEX13C | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs1164157979; called by muse, mutect2
- TG | c.3550G>T p.A1184S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.052); catalogued as rs997010805; called by muse, mutect2, varscan2
- ABCA12 | c.1438G>A p.G480S (on ENST00000272895 / NM_173076.3; = p.G162S on NM_015657.3) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS18 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADGRV1 | c.14312A>C p.Q4771P | Missense Mutation (SNP) | VAF 164/251 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ARNTL | c.776A>T p.K259M | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASXL3 | c.6380T>G p.L2127R | Missense Mutation (SNP) | VAF 79/158 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C1QTNF4 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, mutect2
- C9orf57 | c.109T>A p.L37I (on ENST00000377024 / NM_001371610.1; = p.L15I on NM_001128618.2) | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); called by muse, mutect2
- CACNA1S | c.4555A>G p.T1519A | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.677del p.N226Mfs*4 | Frame Shift Del (DEL) | VAF 16/85 reads (19%) | called by mutect2, varscan2
- CDH8 | c.1898T>G p.L633W | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CRB1 | c.3542G>A p.C1181Y | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CROCC | c.2632C>G p.H878D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTNND2 | c.163_166del p.V55Kfs*10 | Frame Shift Del (DEL) | VAF 18/171 reads (11%) | called by mutect2, pindel
- DMRT3 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DYRK1A | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 211/320 reads (66%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- EHMT2 | c.47A>G p.E16G | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, mutect2
- EPHA6 | c.2040A>C p.E680D (on ENST00000389672 / NM_001080448.3; = p.E72D on NM_173655.4) | Missense Mutation (SNP) | VAF 92/304 reads (30%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBXW4 | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- GABBR2 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- H1-4 | c.242_258del p.K81Tfs*33 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
- HACE1 | c.2102A>C p.D701A | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2
- ITPRIPL2 | c.1514A>G p.Q505R | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM4E | c.1516C>G p.L506V | Missense Mutation (SNP) | VAF 100/148 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLF2 | c.950A>G p.D317G | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHL2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MFSD9 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MRC1 | c.2527_2536del p.E843Ffs*6 | Frame Shift Del (DEL) | VAF 20/151 reads (13%) | called by pindel, varscan2
- NCAM2 | c.121A>C p.T41P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- OR4N5 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 106/198 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- OR5H2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PABPC4L | c.332A>C p.N111T | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); called by muse, mutect2
- PABPC4L | c.330T>A p.D110E | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- PCDHA5 | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2
- PGM3 | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PHLDB1 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 25/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- PPP2R2B | c.23_35del p.L8Hfs*8 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- RPTN | c.1842_1850del p.S616_R618del | In Frame Del (DEL) | VAF 93/213 reads (44%) | called by mutect2, pindel, varscan2
- RRP1B | c.746T>C p.I249T | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.5063C>T p.A1688V | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, varscan2
- SEPTIN9 | c.926T>G p.L309W (on ENST00000427177 / NM_001113491.2; = p.L291W on NM_006640.4) | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMU1 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 59/477 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TLN1 | c.2326C>T p.Q776* | Nonsense Mutation (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- TRRAP | c.2798C>G p.A933G | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TSHZ1 | c.3208T>C p.Y1070H (on ENST00000580243 / NM_001308210.2; = p.Y1025H on NM_005786.6) | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- UNC5CL | c.1070G>T p.C357F | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.171); called by muse, mutect2
- ZNF784 | c.370A>G p.T124A | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, varscan2
- ADCY2 | c.1569C>T p.I523= | Silent (SNP) | VAF 45/285 reads (16%) | called by muse, mutect2, varscan2
- AIRE | c.1071C>T p.P357= | Silent (SNP) | VAF 62/72 reads (86%) | called by muse, mutect2
- ALG1L | c.25C>T p.L9= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1173988149; called by muse, mutect2
- CUL1 | c.978A>G p.V326= | Silent (SNP) | VAF 8/167 reads (5%) | called by muse, mutect2
- FJX1 | c.577C>T p.L193= | Silent (SNP) | VAF 47/132 reads (36%) | called by muse, mutect2, varscan2
- GRIN3B | c.1182G>A p.L394= | Silent (SNP) | VAF 52/166 reads (31%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.132T>G p.S44= | Silent (SNP) | VAF 38/56 reads (68%) | catalogued as rs372598742; called by muse, varscan2
- IGKC | c.306C>T p.F102= | Silent (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- IGKJ4 | c.15A>C p.G5= | Silent (SNP) | VAF 30/30 reads (100%) | catalogued as rs375632806; called by muse, varscan2
- IGLV3-1 | c.132T>C p.D44= | Silent (SNP) | VAF 60/62 reads (97%) | catalogued as rs373697673; called by muse, varscan2
- KIAA1109 | c.14214C>T p.T4738= | Silent (SNP) | VAF 43/176 reads (24%) | called by muse, mutect2, varscan2
- KIF14 | c.2007T>C p.N669= | Silent (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- LINGO4 | c.1365G>A p.L455= | Silent (SNP) | VAF 39/192 reads (20%) | called by muse, mutect2, varscan2
- MAMDC2 | c.492C>T p.T164= | Silent (SNP) | VAF 24/359 reads (7%) | catalogued as rs140482073; called by muse, mutect2
- MUC2 | c.2004C>T p.C668= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as rs377437667; called by muse, mutect2, varscan2
- OR1L6 | c.588C>T p.R196= (on ENST00000373684; = p.R160= on NM_001004453.2) | Silent (SNP) | VAF 103/347 reads (30%) | catalogued as rs761059522; called by muse, mutect2, varscan2
- OVOL2 | c.642C>T p.Y214= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs751840567, COSV53860836; called by mutect2, varscan2
- PCDH9 | c.354C>T p.L118= | Silent (SNP) | VAF 81/167 reads (49%) | called by muse, mutect2, varscan2
- PWP1 | c.543T>C p.D181= | Silent (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- RAB11FIP1 | c.282C>T p.H94= | Silent (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- RYR1 | c.2256G>A p.P752= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as rs149649489; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR2 | c.5010C>T p.H1670= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as rs562273071, COSV100769005, COSV63708384; called by muse, varscan2
- SFTPD | c.1092T>G p.A364= | Silent (SNP) | VAF 49/217 reads (23%) | called by muse, mutect2, varscan2
- SQSTM1 | c.1197C>A p.S399= | Silent (SNP) | VAF 39/218 reads (18%) | called by muse, mutect2, varscan2
- STAB2 | c.5637T>C p.C1879= | Silent (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.27519C>T p.L9173= (on ENST00000591111; = p.L8246= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs758104098, COSV100613598; called by muse, mutect2, varscan2
- UBR5 | c.4950A>G p.S1650= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- ZNF44 | c.1957A>C p.R653= (on ENST00000356109 / NM_001164276.2; = p.R605= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 45/160 reads (28%) | called by muse, mutect2, varscan2
- AACS | c.571-1487G>A | Intron (SNP) | VAF 45/76 reads (59%) | called by muse, mutect2, varscan2
- AIF1L | c.*397C>T | 3'UTR (SNP) | VAF 9/201 reads (4%) | called by muse, mutect2
- AKR1B1P6 | n.178A>T | RNA (SNP) | VAF 66/118 reads (56%) | called by muse, mutect2, varscan2
- AL031777.2 | c.-27G>C | 5'UTR (SNP) | VAF 21/59 reads (36%) | catalogued as rs752585239; called by muse, mutect2, varscan2
- AL645929.2 | chr6:29889459 GG>C | 5'Flank (DEL) | VAF 3/29 reads (10%) | catalogued as rs142456184; called by pindel, varscan2*
- AMOT | c.*120G>A | 3'UTR (SNP) | VAF 74/279 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-108-20G>T | Intron (SNP) | VAF 21/130 reads (16%) | called by muse, mutect2, varscan2
- ARMH3 | c.*1728A>C | 3'UTR (SNP) | VAF 37/74 reads (50%) | called by muse, mutect2, varscan2
- ASAP1 | c.*533G>A | 3'UTR (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- BCL7A | chr12:122021429 G>C | 5'Flank (SNP) | VAF 54/103 reads (52%) | catalogued as COSV55849563, COSV55850516, COSV55852328; called by muse, mutect2, varscan2
- BET1L | c.*1579T>C | 3'UTR (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- BHLHE22 | c.-242C>G | 5'UTR (SNP) | VAF 24/48 reads (50%) | called by muse, mutect2, varscan2
- BTG1 | c.*1374_*1378del | 3'UTR (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- CARD16 | c.7+19C>T | Intron (SNP) | VAF 37/263 reads (14%) | catalogued as rs757172739; called by muse, mutect2, varscan2
- CASKIN1 | c.*256C>A | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- CCSER2 | c.*4452C>T | 3'UTR (SNP) | VAF 40/81 reads (49%) | catalogued as rs778739410; called by muse, mutect2, varscan2
- CDC37L1 | c.*360T>G | 3'UTR (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2
- CEP120 | c.-63C>T | 5'UTR (SNP) | VAF 56/93 reads (60%) | called by muse, mutect2, varscan2
- CERS3 | c.*204T>G | 3'UTR (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- CHST11 | c.204+35_204+36insG | Intron (INS) | VAF 63/152 reads (41%) | called by mutect2, pindel, varscan2
- CHST11 | c.*3944T>C | 3'UTR (SNP) | VAF 35/156 reads (22%) | catalogued as rs1006614750; called by muse, mutect2, varscan2
- CNST | c.*1258A>C | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- COLGALT1 | c.-47C>T | 5'UTR (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- DTWD2 | c.*3516A>C | 3'UTR (SNP) | VAF 41/57 reads (72%) | called by muse, mutect2, varscan2
- DUSP28 | c.-296G>A | 5'UTR (SNP) | VAF 6/23 reads (26%) | catalogued as rs1042776288; called by muse, mutect2, varscan2
- EDA | c.*3840C>T | 3'UTR (SNP) | VAF 12/12 reads (100%) | catalogued as rs752221120; called by muse, varscan2
- EGFL7 | c.*175G>A | 3'UTR (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- EGR3 | c.*2383C>T | 3'UTR (SNP) | VAF 37/60 reads (62%) | called by muse, mutect2, varscan2
- FAM124B | c.732+1019G>T | Intron (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- FLG2 | c.*1718_*1719del | 3'UTR (DEL) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- FOLR3 | c.169-23A>G | Intron (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- GAS8 | c.90+1686G>T | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, varscan2
- GLO1 | c.*100C>G | 3'UTR (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- GRIN2A | c.*706T>C | 3'UTR (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- GUCY1A1 | c.*1542A>G | 3'UTR (SNP) | VAF 6/42 reads (14%) | catalogued as rs370177856; called by muse, mutect2, varscan2
- HSD17B12 | c.*252G>A | 3'UTR (SNP) | VAF 34/102 reads (33%) | catalogued as rs528727998; called by muse, mutect2, varscan2
- IGLV3-21 | c.-73A>G | 5'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- IL21R | c.*895dup | 3'UTR (INS) | VAF 10/41 reads (24%) | catalogued as rs1045570872; called by mutect2, varscan2
- INIP | c.-46A>G | 5'UTR (SNP) | VAF 39/283 reads (14%) | called by muse, mutect2, varscan2
- JAM2 | c.*2696T>G | 3'UTR (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
- KIAA0825 | c.*763C>G | 3'UTR (SNP) | VAF 9/171 reads (5%) | called by muse, mutect2
- KLHL36 | c.*5014G>A | 3'UTR (SNP) | VAF 12/45 reads (27%) | catalogued as rs1278202870; called by muse, mutect2, varscan2
- KRTAP5-11 | c.*274C>T | 3'UTR (SNP) | VAF 150/234 reads (64%) | called by muse, mutect2, varscan2
- LINC01517 | n.702C>T | RNA (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- LPIN2 | c.-9-21837G>T | Intron (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- LRP1B | c.*239G>A | 3'UTR (SNP) | VAF 8/63 reads (13%) | catalogued as rs1193855488; called by muse, mutect2, varscan2
- LZIC | chr1:9929420 A>G | 3'Flank (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- MAL | c.-15C>T | 5'UTR (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2
- MAN1C1 | c.*1159G>A | 3'UTR (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- MED15 | chr22:20507549 C>A | 5'Flank (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851342 C>T | 5'Flank (SNP) | VAF 56/131 reads (43%) | catalogued as rs544762978; called by muse, mutect2, varscan2
- MROH7 | c.2964+2324A>T | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- MYO3A | c.731+106A>C | Intron (SNP) | VAF 85/199 reads (43%) | catalogued as COSV56335917; called by muse, mutect2, varscan2
- MYO3A | c.732-857T>A | Intron (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- MYO5A | c.*5631A>G | 3'UTR (SNP) | VAF 94/184 reads (51%) | called by muse, varscan2
- MYT1L | c.*2374G>A | 3'UTR (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- NKAPL | c.-23C>A | 5'UTR (SNP) | VAF 21/131 reads (16%) | catalogued as rs755524580, COSV100642569; called by muse, mutect2, varscan2
- OR13J1 | c.-142G>A | 5'UTR (SNP) | VAF 7/72 reads (10%) | catalogued as rs547175884, COSV65070329; called by muse, mutect2
- OXSR1 | c.*2274A>T | 3'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- PAPOLG | c.*3795T>A | 3'UTR (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- PAX1 | c.*517T>G | 3'UTR (SNP) | VAF 49/102 reads (48%) | called by muse, mutect2, varscan2
- PHF20L1 | c.*1714A>C | 3'UTR (SNP) | VAF 65/120 reads (54%) | called by muse, mutect2, varscan2
- PIGK | c.*2740A>T | 3'UTR (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- PON2 | c.*291A>G | 3'UTR (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- PPP1R9A | c.*1064T>G | 3'UTR (SNP) | VAF 34/53 reads (64%) | called by muse, mutect2, varscan2
- PSEN1 | c.*1881T>C | 3'UTR (SNP) | VAF 52/93 reads (56%) | called by muse, mutect2, varscan2
- PTCHD4 | c.908-21971G>A | Intron (SNP) | VAF 8/194 reads (4%) | catalogued as COSV59783208; called by muse, mutect2
- PTPRR | c.*381T>G | 3'UTR (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- RAPGEF2 | c.*1017T>G | 3'UTR (SNP) | VAF 5/38 reads (13%) | catalogued as rs371580242, COSV52424437; called by muse, varscan2
- RBM6 | c.*92T>C | 3'UTR (SNP) | VAF 29/170 reads (17%) | called by muse, mutect2, varscan2
- REEP6 | c.*505G>A | 3'UTR (SNP) | VAF 38/486 reads (8%) | catalogued as rs757007279; called by muse, mutect2
- RNF125 | c.*4276G>T | 3'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- SH2D3C | c.556-3488G>A | Intron (SNP) | VAF 17/123 reads (14%) | catalogued as rs749610886; called by muse, mutect2, varscan2
- SLC1A2 | c.*8896T>C | 3'UTR (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- SLC22A2 | c.1064+219G>A | Intron (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- SLC24A4 | c.*1669C>T | 3'UTR (SNP) | VAF 12/172 reads (7%) | catalogued as rs1356266946; called by muse, mutect2
- SLITRK1 | c.*871del | 3'UTR (DEL) | VAF 26/63 reads (41%) | called by mutect2, pindel, varscan2
- SNRPE | c.54+22G>C | Intron (SNP) | VAF 8/219 reads (4%) | catalogued as COSV100919314; called by muse, mutect2
- SNX20 | c.*1499A>T | 3'UTR (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- SOGA1 | c.*3315G>A | 3'UTR (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- SPANXN3 | c.*31C>A | 3'UTR (SNP) | VAF 12/288 reads (4%) | catalogued as COSV100980838; called by muse, mutect2
- SPATC1L | c.*57del | 3'UTR (DEL) | VAF 13/96 reads (14%) | called by mutect2, varscan2
- SSR3 | c.*2074T>C | 3'UTR (SNP) | VAF 33/114 reads (29%) | catalogued as rs1045639591; called by muse, mutect2, varscan2
- SV2C | c.*776C>A | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- TFG | c.*145T>C | 3'UTR (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- TG | c.5549-1644_5549-1616del | Intron (DEL) | VAF 8/89 reads (9%) | called by mutect2, pindel
- TLN2 | c.-36-9821G>A | Intron (SNP) | VAF 31/182 reads (17%) | called by muse, mutect2, varscan2
- TNFAIP1 | c.*1468T>C | 3'UTR (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- TNS3 | c.4193+51C>T | Intron (SNP) | VAF 33/293 reads (11%) | called by muse, mutect2, varscan2
- TSNAXIP1 | c.1736+50C>T | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- TTC7A | c.*273A>G | 3'UTR (SNP) | VAF 22/168 reads (13%) | called by muse, mutect2, varscan2
- TXNDC5 | c.*972T>C | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- UBE3A | c.-37+35T>C | Intron (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- ULK2 | c.*40+1937T>A | Intron (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- UNC13A | c.*300T>C | 3'UTR (SNP) | VAF 25/174 reads (14%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439020 T>C | 5'Flank (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.*701T>C | 3'UTR (SNP) | VAF 17/334 reads (5%) | called by muse, mutect2
